TARGET case TARGET-15-SJMPAL044945 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79c5a984-6a22-4e64-88e7-e95813828561

Demographics
Sex at birth: female; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.6 years (2,776 days); Year of diagnosis: 2010; Days to last follow up: 1,089 days (3.0 years).

Follow-up (1 entry)
- Days to follow up: 1,089 days (3.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,089; Year of follow up: 2013.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 5.4 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL044945-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1089
- Protocol: DCOG
- WBC at Diagnosis: 5.4
- Initial Therapy: ALL
- Karyotype: 46,XX,t(6;14)(q25;q32.1)[18]/45,XX,t(6;14)(q25;q32.1),-13,-13,?add(15)(p11),-16,-16,?20,+der(?)t(?;13)(?;q14),+der(?)t(?;16)(?;q11),+der(?)t(?;16)(?;q11)[4]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
